CCDI case PBCUZH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/8bc4c9d4-5331-4e50-b9e9-80f1ef6a4b39

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E0A0B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E0A0Q: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
